Gene-level copy-number profile of tumor specimen ALCH-B067-TTR1-A from ALCHEMIST case ALCH-B067, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.1 years (24,522 days).
Specimen ALCH-B067-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file badcbfd2-dca2-480b-a8cb-d18d7b3c05cf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B067-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,751 have no estimate.
https://portal.gdc.cancer.gov/files/cb1b9d62-5fea-465f-8d2f-c40f69257196

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 639; copy number 1: 34,012; copy number 2: 22,811; copy number 3: 1,405; copy number 4: 1; copy number 5: 2; copy number 21: 2.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:157,085,832–157,159,019, 3 genes (within-gene range 0–1): HAVCR2, AC011377.1, MED7.
- chr6:73,593,379–73,653,992, 2 genes: SLC17A5, RPS27P15.
- chr6:151,319,635–151,391,559, 3 genes (within-gene range 0–1): RN7SKP268, ZBTB2, Y_RNA.
- chr9:6,413,151–6,727,438, 13 genes (within-gene range 0–1): UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,748,981, 2 genes (within-gene range 0–1): PRELID3BP11, SNRPEP2.
- chr9:8,700,595–8,797,194, 3 genes (within-gene range 0–1): AL583805.2, AL583805.1, RNU7-185P.
- chr9:8,936,079–8,963,077, 1 gene (within-gene range 0–1): AL596451.1.
- chr9:15,422,704–15,544,294, 7 genes: SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:15,588,355–15,588,615, 1 gene (within-gene range 0–1): HMGN2P16.
- chr9:34,179,005–34,252,523, 5 genes (within-gene range 0–1): UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1.
- chr9:42,579,414–42,714,539, 5 genes: BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr10:68,282,660–68,472,121, 6 genes: PBLD, HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319.
- chr10:133,230,217–133,312,337, 8 genes (within-gene range 0–1): UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2.
- chr10:133,344,643–133,350,726, 2 genes (within-gene range 0–1): BANF1P2, AL360181.1.
- chr10:133,355,158–133,358,025, 1 gene: FUOM.
- chr14:36,320,753–36,656,163, 1 gene (within-gene range 0–1): AL132857.1.
- chr14:36,473,207–36,679,362, 10 genes (within-gene range 0–1): SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9.
- chr14:36,788,644–36,828,729, 2 genes (within-gene range 0–1): AL162464.2, AL162464.1.
- chr14:63,543,569–63,736,505, 14 genes: AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P.
- chr14:63,762,013–63,762,149, 1 gene: AL161670.1.
- chr15:21,293,653–21,295,201, 1 gene: AC068446.1.
- chr15:21,980,277–21,981,245, 1 gene: OR11J6P.
- chr16:33,577,502–33,771,248, 4 genes (within-gene range 0–1): AC142384.1, BMS1P8, ENPP7P13, AC136428.2.
- chr17:410,325–431,062, 1 gene (within-gene range 0–1): C17orf97.
- chr20:32,449,755–32,453,607, 1 gene (within-gene range 0–2): AL034550.1.
- chr20:63,941,465–63,956,985, 2 genes (within-gene range 0–1): MIR1914, UCKL1-AS1.
- chr21:8,759,077–9,083,101, 11 genes (within-gene range 0–2): LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, SOWAHCP2.
- chr21:37,045,530–37,045,636, 1 gene: RNU6-696P.
- chr21:42,843,094–42,879,568, 1 gene: WDR4.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,410 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:778,747–817,712, 3 genes, copy number 3 (within-gene range 2–3): LINC01409, AL669831.6, AL669831.4.
- chr2:232,406,844–232,410,714, 1 gene, copy number 3: ALPG.
- chr5:58,198–58,915, 1 gene, copy number 4: AC113430.1.
- chr6:31,268,749–31,478,936, 22 genes, copy number 3: HLA-C, USP8P1, RPL3P2, WASF5P, LINC02571, AL671883.1, HLA-B, MIR6891, AL671883.2, DHFRP2, AL671883.3, RNU6-283P, FGFR3P1, ZDHHC20P2, HLA-S, AL645933.2, MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5.
- chr6:60,719,222–60,723,898, 2 genes, copy number 3: GAPDHP41, AL590227.1.
- chr6:60,826,185–60,826,533, 1 gene, copy number 3: AL512427.1.
- chr8:46,028,804–139,508,971, 1,291 genes, copy number 3 (broad region; genes not listed).
- chr9:42,566,679–42,569,353, 2 genes, copy number 3: BX088651.4, BX088651.1.
- chr11:55,262,155–55,284,749, 4 genes, copy number 3: TRIM48, AP005597.4, AP005597.3, AP005597.2.
- chr15:21,927,657–21,951,323, 2 genes, copy number 5: NF1P2, MIR5701-3.
- chr16:88,186,605–88,195,217, 2 genes, copy number 21: LINC02182, AC134312.6.
- chr17:50,158,333–50,215,922, 7 genes, copy number 3: AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4.
- chr17:73,334,384–74,154,212, 10 genes, copy number 3: SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, LINC02074.
- chr17:74,466,399–74,776,367, 16 genes, copy number 3: CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1, CD300E, AC064805.2, RAB37, CD300LF, AC016888.1, MIR3615, SLC9A3R1, NAT9.
- chr19:41,449,520–41,555,462, 6 genes, copy number 3 (within-gene range 2–3): PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1.
- chr19:41,551,568–41,552,274, 1 gene, copy number 3 (within-gene range 2–3): AC243960.10.
- chr20:1,442,162–1,473,842, 1 gene, copy number 3 (within-gene range 2–3): NSFL1C.
- chr21:45,234,308–45,264,548, 1 gene, copy number 3 (within-gene range 2–3): LINC00334.
- chr22:22,664,473–22,858,268, 36 genes, copy number 3: IGLV2-28, IGLV3-27, IGLV3-26, IGLVVI-25-1, IGLV3-25, AC244250.2, AC244250.1, IGLV3-24, IGLV2-23, IGLVVI-22-1, IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17, IGLV3-16, IGLV3-15, IGLV2-14, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4.
- chr22:22,887,780–22,896,111, 1 gene, copy number 3 (within-gene range 2–3): IGLL5.

Autosomal genes at a single copy (total copy number 1): 31,685. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
